TCGA case TCGA-BC-A69H — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: UNC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/79df037c-7d37-4e6c-a654-57708a4f87aa

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 64 years; Vital status: Alive.

Diagnoses (1)
1. Hepatocellular carcinoma, NOS: ICD-O-3 morphology code: 8170/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 64.0 years (23,380 days); Year of diagnosis: 2013; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 444 days (1.2 years); Child pugh classification: A.
   Pathology details: Consistent pathology review: Yes; Vascular invasion present: Yes; Vascular invasion type: Micro.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 120 days; Disease response: Tumor Free.
- Days to follow up: 444 days (1.2 years); Disease response: Tumor Free.
- ECOG performance status: 1.

Molecular and laboratory tests
- Alpha Fetoprotein 103900 ng/mL [Blood test normal range lower: 0].
- Albumin 4.3 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.6; Blood test normal range upper: 4.8].
- Creatinine 0.8 mg/dL [Blood test normal range lower: 0.8; Blood test normal range upper: 1.3].
- Prothrombin Time 10.7 Seconds [Blood test normal range lower: 9.1; Blood test normal range upper: 12].
- Total Bilirubin 0.4 mg/dL [Blood test normal range lower: 0; Blood test normal range upper: 1.2].
- Platelets 194000 (unit not recorded by GDC) [Blood test normal range lower: 140000; Blood test normal range upper: 440000].

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Alcohol Consumption.
- Timepoint category: Initial Diagnosis; Weight: 70 kg; Height: 173 cm; BMI: 23.4.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BC-A69H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 610 mg.
  Slide TCGA-BC-A69H-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 14; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.
- Sample TCGA-BC-A69H-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BC-A69H-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Histologic diagnosis: Hepatocellular Carcinoma; Definitive surgical procedure: Segmentectomy, Multiple; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 444 days; disease-specific survival: no event (censored), 444 days; disease-free interval: no event (censored), 444 days; progression-free interval: no event (censored), 444 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BC-A69H-01A-11D-A30U-01): tumor purity 0.66, ploidy 4.01, whole-genome doublings 2.
